Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A39S, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A39S-01A (Primary Tumor).

HIIPAA Discrepancy		

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

THYROID (TOTAL THYROIDECTOMY):

SPECIMEN TYPE:

Total thyroidectomy.

TUMOR SITE:

Left lobe.

100-0-3

carcinoma, papillary, thyroid 8260/3

HISTOLOGIC TYPE:

Papillary carcinoma.

Site: thyroid, nos C73.9

fw
9/14/11

TUMOR SIZE:

1.0 CM greatest dimension.

FOCALITY:

Unifocal.

LYMPH NODES:

All TWO (2) lymph nodes are negative for tumor.

EXTENT OF INVASION

PRIMARY TUMOR:

pT1: Tumor size <2 cm, limited to thyroid.

REGIONAL LYMPH NODES:

pNO: No regional lymph node metastases.

DISTANT METASTASIS:

pMx: Cannot be assessed.

MARGINS:

Margins are uninvolved.

Distance of invasive carcinoma from nearest margin: <1 mm (anterior and posterior).

VENOUS/LYMPHATIC INVASION:

Absent.

ADDITIONAL PATHOLOGIC FINDINGS:

None identified.

Source: NCI Genomic Data Commons file e66accef-2470-4f07-b2fa-e2582661b7fc (TCGA-ET-A39S.2E9B4821-BC11-4BE9-9420-01B5C16B3270.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).